Somatic mutation profile of tumor specimen BA3370D (aliquot aq-BA3370D) from BEATAML1.0 case 2675, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.3 years (25,324 days).
Specimen BA3370D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2b357ef-169c-49af-8627-332e47d97d75.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3429D (Solid Tissue Normal), aliquot aq-BA3429D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b7827f-0237-45c9-bd1f-e42579131137

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- STAG2 | c.2411C>G p.S804* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV54357318; called by muse, mutect2, varscan2
- ASXL1 | c.1891C>A p.H631N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.237); called by muse, varscan2
- STAG2 | c.1183dup p.T395Nfs*7 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.4605G>A p.V1535= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- CADPS | c.4047C>T p.D1349= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs780719627, COSV51871541; called by muse, mutect2, varscan2
- PRAMEF1 | c.34C>T p.L12= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV60005400; called by muse, mutect2
- RGS22 | c.2979C>T p.L993= | Silent (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- CHADL | c.-38C>T | 5'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs1017202057; called by muse, mutect2, varscan2
